Gene-level copy-number profile of tumor specimen ALCH-B2MO-TTP1-A from ALCHEMIST case ALCH-B2MO, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.0 years (25,196 days).
Specimen ALCH-B2MO-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a9c8c423-9c11-4b17-9be1-e8eddb5e83c3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2MO-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,217 have no estimate.
https://portal.gdc.cancer.gov/files/5a69810b-b1a0-4617-a113-1a1d65985e2c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 2,849; copy number 2: 53,513; copy number 3: 1,974; copy number 4: 66.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:41,493,393–41,513,887, 2 genes: ITPKA, LTK.
- chr15:43,510,958–43,531,620, 1 gene: MAP1A.
- chr17:2,072,823–2,072,956, 1 gene (within-gene range 0–2): AC090617.9.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,234. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
